Somatic mutation profile of tumor specimen TCGA-IB-7889-01A (aliquot TCGA-IB-7889-01A-11D-2154-08) from TCGA case TCGA-IB-7889, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 85.9 years (31,393 days).
Specimen TCGA-IB-7889-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8ad5661-e2c0-4f83-b455-d6b6ced53130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7889-10A (Blood Derived Normal), aliquot TCGA-IB-7889-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52a5d65a-6ff0-4e05-a4e2-aeafad7a8f03

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 24, Silent 15, Nonsense Mutation 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 35/314 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 42/444 reads (9%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS18 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 31/532 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147816593; called by muse, mutect2
- ADAMTSL4 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 57/1228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775141488, COSV99647380; ClinVar: uncertain significance; called by muse, mutect2
- ASH2L | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1563248967, COSV51701884; called by muse, mutect2
- BOD1L1 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs867893567, COSV50131153; called by muse, mutect2
- BPTF | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 94/822 reads (11%) | catalogued as COSV100075040; called by muse, mutect2, varscan2
- CADM3 | c.427C>T p.R143W (on ENST00000368125 / NM_001127173.3; = p.R177W on NM_021189.5) | Missense Mutation (SNP) | VAF 92/459 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1021719284, COSV100930343; called by muse, mutect2, varscan2
- CDH20 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs768687010, COSV53006442; called by muse, mutect2
- CXCR4 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 15/438 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV54010328; called by muse, mutect2
- CYP4F22 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99512820; called by muse, mutect2
- FOXQ1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 18/317 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1369904204, COSV99723292; called by muse, mutect2
- IGSF9 | c.1883G>A p.R628Q (on ENST00000368094 / NM_001135050.2; = p.R612Q on NM_020789.4) | Missense Mutation (SNP) | VAF 141/692 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.169); catalogued as COSV100829632; called by muse, mutect2, varscan2
- LCT | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 38/550 reads (7%) | catalogued as rs1291540757, COSV51545152; called by muse, mutect2
- MYOZ1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100831865; called by muse, mutect2
- MYOZ1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100831866; called by muse, mutect2
- OR10Q1 | c.878T>C p.L293S | Missense Mutation (SNP) | VAF 54/774 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100372292; called by muse, mutect2
- PAPPA2 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs376402363, COSV62795460; called by muse, mutect2
- PRKG1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64788793; called by muse, mutect2, varscan2
- RGS22 | c.790T>A p.L264M | Missense Mutation (SNP) | VAF 60/1090 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.293); catalogued as COSV100693296; called by muse, mutect2
- RIT1 | c.108C>A p.A36= | Splice Region (SNP) | VAF 54/353 reads (15%) | catalogued as COSV100850951; called by muse, mutect2, varscan2
- SECISBP2L | c.2463G>T p.M821I (on ENST00000559471 / NM_001193489.2; = p.M776I on NM_014701.4) | Missense Mutation (SNP) | VAF 51/1169 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99960402; called by muse, mutect2
- SLC52A1 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 52/657 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.117); catalogued as COSV99643423; called by muse, mutect2
- SYNPO2 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100205652; called by muse, mutect2, varscan2
- TRPS1 | c.1832G>A p.R611Q (on ENST00000220888 / NM_001330599.2; = p.R624Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.921); catalogued as rs762850704, COSV99631206; called by muse, mutect2, varscan2
- TSHZ2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 36/547 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs779892655, COSV61589413; called by muse, mutect2
- ZAN | c.6515A>T p.E2172V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100769761; called by muse, mutect2
- CACNA2D2 | c.2289C>T p.D763= (on ENST00000479441 / NM_001174051.3; = p.D756= on NM_006030.4) | Silent (SNP) | VAF 29/321 reads (9%) | catalogued as rs375235408; called by muse, mutect2
- DRG2 | c.472C>T p.L158= | Silent (SNP) | VAF 79/907 reads (9%) | catalogued as rs200673460; called by muse, mutect2
- GPR182 | c.423C>T p.I141= | Silent (SNP) | VAF 36/374 reads (10%) | catalogued as COSV100267730; called by muse, mutect2
- MIEF2 | c.1117C>T p.L373= | Silent (SNP) | VAF 19/716 reads (3%) | catalogued as rs1231296461; called by muse, mutect2
- MUC16 | c.16209G>A p.P5403= | Silent (SNP) | VAF 99/1864 reads (5%) | catalogued as rs373387179; called by muse, mutect2
- NF1 | c.4062C>T p.S1354= | Silent (SNP) | VAF 21/696 reads (3%) | catalogued as COSV100647166; called by muse, mutect2
- NOCT | c.711C>T p.A237= | Silent (SNP) | VAF 31/436 reads (7%) | catalogued as COSV99763873; called by muse, mutect2
- PCDHB13 | c.1866C>T p.G622= | Silent (SNP) | VAF 28/576 reads (5%) | called by muse, mutect2
- PKN3 | c.1797C>T p.D599= | Silent (SNP) | VAF 14/300 reads (5%) | catalogued as rs1233666244, COSV52578668; called by muse, mutect2
- PRKAR1B | c.261G>A p.P87= | Silent (SNP) | VAF 57/529 reads (11%) | catalogued as rs545804273, COSV64317682; called by muse, mutect2, varscan2
- RNF144A | c.498C>G p.P166= | Silent (SNP) | VAF 65/594 reads (11%) | called by muse, mutect2, varscan2
- SLC28A1 | c.846C>T p.H282= | Silent (SNP) | VAF 46/944 reads (5%) | catalogued as rs369148182, COSV99722998; called by muse, mutect2
- SPAM1 | c.1111C>T p.L371= | Silent (SNP) | VAF 40/367 reads (11%) | catalogued as rs146075363; called by muse, mutect2, varscan2
- ST8SIA2 | c.345A>G p.G115= | Silent (SNP) | VAF 138/1092 reads (13%) | catalogued as rs369714591; called by muse, mutect2, varscan2
- TEPP | c.39G>A p.L13= | Silent (SNP) | VAF 31/492 reads (6%) | catalogued as COSV99333061; called by muse, mutect2
